Somatic mutation profile of tumor specimen TCGA-HC-7821-01A (aliquot TCGA-HC-7821-01A-12D-2114-08) from TCGA case TCGA-HC-7821, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.5 years (19,894 days).
Specimen TCGA-HC-7821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08a91d10-4270-47b0-8bb6-ab3344b5c010.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7821-10A (Blood Derived Normal), aliquot TCGA-HC-7821-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a84a8e78-6165-4137-bb68-71ae8e72cfa7

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH8 | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54852039, COSV54868465; called by muse, mutect2, varscan2
- CNOT3 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745387907, COSV55363451; called by muse, mutect2, varscan2
- CUBN | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs564637804, COSV64713872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJB5 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1385834881, COSV58356223; called by muse, mutect2, varscan2
- MLXIP | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59835371; called by muse, mutect2
- OTUD7A | c.1526G>A p.R509H (on ENST00000307050 / NM_001382637.1; = p.R502H on NM_130901.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs770898697, COSV61039011; called by muse, mutect2
- P2RY10 | c.99A>T p.Q33H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1271792006, COSV50681503; called by muse, mutect2, varscan2
- PCDHGA1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.42); catalogued as rs758199803, COSV65296647; called by muse, mutect2, varscan2
- PCDHGC3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs761453939, COSV52752855; called by muse, mutect2, varscan2
- PLEKHA6 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV55333963; called by muse, mutect2, varscan2
- PRKDC | c.4337G>A p.S1446N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as COSV58052728; called by muse, mutect2, varscan2
- RYR2 | c.12215C>A p.T4072K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV63686845, COSV63697649; called by muse, mutect2
- THRAP3 | c.2720G>A p.G907D | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV57176634; called by muse, mutect2, varscan2
- TMEM255A | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 120/183 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs782600983, COSV59028934; called by muse, mutect2, varscan2
- ZNF354B | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- ALPK2 | c.1821G>A p.Q607= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as rs1178470184, COSV64493183; called by muse, mutect2, varscan2
- BRCA2 | c.2799A>T p.T933= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV66454243; called by muse, mutect2, varscan2
- C20orf85 | c.48T>G p.L16= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV64519372; called by muse, mutect2, varscan2
- CD46 | c.175C>A p.R59= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as CM062495, COSV100522838, COSV59733305; called by muse, mutect2, varscan2
- EARS2 | c.480G>C p.T160= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV71942734, COSV71942842; called by muse, mutect2, varscan2
- KRT33A | c.1134T>C p.C378= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV50367244; called by muse, mutect2, varscan2
- NLRP8 | c.1455C>T p.T485= | Silent (SNP) | VAF 67/156 reads (43%) | catalogued as rs780563272, COSV52584258, COSV52584537; called by muse, mutect2, varscan2
- NPTX2 | c.711C>T p.Y237= | Silent (SNP) | VAF 84/206 reads (41%) | catalogued as rs573416055, COSV55717304, COSV55717885; called by muse, mutect2, varscan2
- KIF16B | c.3498+3063G>T | Intron (SNP) | VAF 23/62 reads (37%) | catalogued as COSV61706457; called by muse, mutect2, varscan2
